Somatic mutation profile of tumor specimen C3N-02262-02 (aliquot CPT0188140011) from CPTAC case C3N-02262, project CPTAC-3 (Kidney — Adenomas and Adenocarcinomas). Sex at birth: male; Vital status: Alive; Primary diagnosis: Renal cell carcinoma, NOS; Tissue or organ of origin: Kidney, NOS; AJCC pathologic stage: Stage I; Tumor grade: G3; Age at diagnosis: 67.3 years (24,568 days).
Specimen C3N-02262-02: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Kidney; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) ac109eb4-2c99-4fd2-b4a7-43bcf18cbdf9.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen C3N-02262-31 (Blood Derived Normal), aliquot CPT0188170002; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/8442c4a0-7062-4877-a891-6798e124173f

The open-access MAF lists 171 somatic variants for this specimen: 120 protein-altering or splice-affecting, 33 silent, 18 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 101, Silent 33, Nonsense Mutation 10, Intron 10, Frame Shift Ins 4, Frame Shift Del 3, 3'UTR 3, 5'UTR 3, RNA 2, Splice Site 1, In Frame Ins 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ANKRD30A | c.1150G>A p.A384T (on ENST00000611781; = p.A328T on NM_052997.2) | Missense Mutation (SNP) | VAF 35/287 reads (12%) | SIFT tolerated (0.96); PolyPhen possibly damaging (0.499); catalogued as rs772987097, COSV64610212; called by muse, mutect2, varscan2
- AP3B2 | c.2886G>C p.Q962H (on ENST00000261722; = p.Q956H on NM_004644.5) | Missense Mutation (SNP) | VAF 34/177 reads (19%) | SIFT tolerated (0.47); PolyPhen benign (0.026); catalogued as rs766170760; called by muse, mutect2, varscan2
- ARHGEF25 | c.929A>G p.N310S | Missense Mutation (SNP) | VAF 47/240 reads (20%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs1424455112, COSV54090321; called by muse, mutect2, varscan2
- ARMS2 | c.38C>T p.A13V | Missense Mutation (SNP) | VAF 39/207 reads (19%) | SIFT tolerated, low confidence (0.63); PolyPhen benign (0); catalogued as rs781450432; called by muse, mutect2, varscan2
- ARPC2 | c.878C>T p.T293M | Missense Mutation (SNP) | VAF 16/147 reads (11%) | SIFT deleterious (0); PolyPhen benign (0.072); catalogued as rs374047289; called by muse, mutect2, varscan2
- ASXL1 | c.3269G>A p.R1090K | Missense Mutation (SNP) | VAF 32/290 reads (11%) | SIFT tolerated (0.29); PolyPhen benign (0.015); catalogued as COSV60114452; called by muse, mutect2, varscan2
- ATP8B2 | c.3476G>A p.R1159H (on ENST00000672630; = p.R1126H on NM_001367934.1 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 41/349 reads (12%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); catalogued as rs750929591, COSV63831551, COSV63832667; called by muse, mutect2, varscan2
- ATP8B3 | c.419C>T p.T140M | Missense Mutation (SNP) | VAF 31/250 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs372598351; called by muse, mutect2, varscan2
- AXIN1 | c.1244G>A p.R415H | Missense Mutation (SNP) | VAF 295/680 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.911); catalogued as rs368340732; called by muse, mutect2, varscan2
- BMP7 | c.49C>T p.L17F | Missense Mutation (SNP) | VAF 65/585 reads (11%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0.005); catalogued as rs1482615161; called by muse, mutect2, varscan2
- CLIP2 | c.2590G>A p.E864K | Missense Mutation (SNP) | VAF 41/157 reads (26%) | SIFT deleterious (0); PolyPhen benign (0.373); catalogued as rs782008375, COSV56282484, COSV56287235; called by muse, mutect2, varscan2
- DOCK2 | c.5288C>G p.A1763G | Missense Mutation (SNP) | VAF 22/154 reads (14%) | SIFT tolerated, low confidence (1); PolyPhen benign (0.001); catalogued as COSV99916176; called by mutect2, varscan2
- DOCK4 | c.2737G>A p.G913R | Missense Mutation (SNP) | VAF 26/120 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.937); catalogued as rs748360021, COSV70237099; called by muse, mutect2, varscan2
- DRC7 | c.487C>T p.P163S | Missense Mutation (SNP) | VAF 18/94 reads (19%) | SIFT tolerated (0.52); PolyPhen benign (0.117); catalogued as rs761733599; called by muse, mutect2, varscan2
- ERCC6 | c.3662G>A p.R1221Q | Missense Mutation (SNP) | VAF 48/141 reads (34%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.926); catalogued as rs200431100, COSV63389936; called by muse, mutect2
- GPR161 | c.373C>T p.R125C | Missense Mutation (SNP) | VAF 12/69 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.966); catalogued as rs756665853; called by muse, mutect2, varscan2
- GPRIN1 | c.2186G>A p.R729H | Missense Mutation (SNP) | VAF 27/116 reads (23%) | SIFT tolerated (0.07); PolyPhen benign (0); catalogued as rs1407864927, COSV56146491; called by muse, mutect2, varscan2
- GRK7 | c.890C>T p.S297L | Missense Mutation (SNP) | VAF 85/325 reads (26%) | SIFT deleterious (0); PolyPhen benign (0.266); catalogued as rs201386342, COSV53821577; called by muse, mutect2, varscan2
- HOXD13 | c.185C>T p.A62V | Missense Mutation (SNP) | VAF 24/189 reads (13%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.448); catalogued as rs781428411; called by muse, mutect2, varscan2
- IRGC | c.1109C>A p.T370K | Missense Mutation (SNP) | VAF 163/423 reads (39%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.719); catalogued as COSV54985382, COSV54985603; called by muse, mutect2, varscan2
- KIF1C | c.2584C>T p.R862W | Missense Mutation (SNP) | VAF 7/41 reads (17%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.985); catalogued as rs764833076, COSV57903187; called by muse, mutect2, varscan2
- LIMS2 | c.879-1G>A p.X293_splice (on ENST00000355119 / NM_001161403.3; = p.X317_splice on NM_017980.4) | Splice Site (SNP) | VAF 21/86 reads (24%) | catalogued as COSV61444510; called by muse, mutect2, varscan2
- LRGUK | c.1292C>T p.A431V | Missense Mutation (SNP) | VAF 24/250 reads (10%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.97); catalogued as COSV53645140; called by muse, mutect2
- LRP2 | c.7066C>T p.L2356F | Missense Mutation (SNP) | VAF 50/412 reads (12%) | SIFT tolerated (0.38); PolyPhen benign (0.01); catalogued as rs1267326056; called by muse, mutect2, varscan2
- MTHFR | c.760C>G p.P254A | Missense Mutation (SNP) | VAF 14/120 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs786204017, CM155652; called by muse, mutect2, varscan2
- MUC4 | c.7604C>T p.S2535F | Missense Mutation (SNP) | VAF 88/1172 reads (8%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.496); catalogued as rs779036713; called by muse, mutect2
- NELL1 | c.1698C>G p.C566W | Missense Mutation (SNP) | VAF 45/397 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV54330284; called by muse, mutect2, varscan2
- NRROS | c.175G>A p.A59T | Missense Mutation (SNP) | VAF 12/105 reads (11%) | SIFT tolerated (0.69); PolyPhen benign (0); catalogued as rs1181456534, COSV60747963; called by muse, mutect2
- PBRM1 | c.292C>T p.Q98* | Nonsense Mutation (SNP) | VAF 40/142 reads (28%) | catalogued as COSV56273351; called by muse, mutect2, varscan2
- PCDH15 | c.4312C>T p.P1438S | Missense Mutation (SNP) | VAF 27/193 reads (14%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.028); catalogued as rs779149856; called by muse, mutect2, varscan2
- PCDH7 | c.822C>G p.Y274* | Nonsense Mutation (SNP) | VAF 32/268 reads (12%) | catalogued as COSV62338579; called by muse, mutect2, varscan2
- PLXNA1 | c.5627C>T p.A1876V | Missense Mutation (SNP) | VAF 23/197 reads (12%) | SIFT deleterious (0.01); PolyPhen benign (0.158); catalogued as rs569026320, COSV52526029; called by muse, mutect2, varscan2
- PRAMEF12 | c.211A>T p.K71* | Nonsense Mutation (SNP) | VAF 65/247 reads (26%) | catalogued as COSV100743328; called by muse, mutect2, varscan2
- PRUNE2 | c.7264C>G p.L2422V | Missense Mutation (SNP) | VAF 25/148 reads (17%) | SIFT tolerated (0.14); PolyPhen benign (0.122); catalogued as COSV100944855; called by muse, mutect2, varscan2
- R3HDML | c.477G>A p.W159* | Nonsense Mutation (SNP) | VAF 9/83 reads (11%) | catalogued as rs751588439; called by muse, mutect2, varscan2
- RC3H1 | c.2416G>A p.D806N | Missense Mutation (SNP) | VAF 18/159 reads (11%) | SIFT tolerated (0.15); PolyPhen benign (0.001); catalogued as COSV51209235; called by muse, varscan2
- RRBP1 | c.2665C>T p.R889W (on ENST00000377813 / NM_001365613.2; = p.R456W on NM_004587.3) | Missense Mutation (SNP) | VAF 38/331 reads (11%) | SIFT deleterious (0.02); PolyPhen benign (0.003); catalogued as rs754757680; called by muse, mutect2, varscan2
- SDS | c.293G>A p.R98H | Missense Mutation (SNP) | VAF 24/310 reads (8%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.908); catalogued as rs780495084, COSV57454526; called by muse, mutect2
- SH3TC2 | c.94T>A p.C32S | Missense Mutation (SNP) | VAF 66/275 reads (24%) | SIFT tolerated (0.41); PolyPhen benign (0.003); catalogued as COSV100101814, COSV60461834; called by muse, mutect2, varscan2
- SLC17A8 | c.1681G>A p.E561K | Missense Mutation (SNP) | VAF 22/192 reads (11%) | SIFT tolerated (0.62); PolyPhen benign (0.017); catalogued as rs750384271, COSV60124350; called by muse, mutect2, varscan2
- SOBP | c.2050G>A p.A684T | Missense Mutation (SNP) | VAF 14/180 reads (8%) | SIFT tolerated, low confidence (0.11); PolyPhen benign (0.018); catalogued as rs1375120443; called by muse, mutect2
- STAB2 | c.6082G>A p.G2028R | Missense Mutation (SNP) | VAF 30/350 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.941); catalogued as rs758072314, COSV101185861; called by muse, mutect2
- TRAK2 | c.1030C>T p.Q344* | Nonsense Mutation (SNP) | VAF 30/136 reads (22%) | catalogued as COSV100216768; called by muse, mutect2, varscan2
- TRPC4AP | c.668G>A p.R223Q | Missense Mutation (SNP) | VAF 22/190 reads (12%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as rs759862385, COSV52681277; called by muse, mutect2, varscan2
- TRPM5 | c.2330C>T p.T777M | Missense Mutation (SNP) | VAF 12/96 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as rs895214608; called by muse, mutect2, varscan2
- TTC5 | c.367C>T p.H123Y | Missense Mutation (SNP) | VAF 96/194 reads (49%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.472); catalogued as rs1378317793; called by muse, mutect2, varscan2
- VMAC | c.466G>C p.D156H | Missense Mutation (SNP) | VAF 35/445 reads (8%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.627); catalogued as rs866158418; called by muse, mutect2
- ZNF536 | c.565C>T p.R189C | Missense Mutation (SNP) | VAF 34/265 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1293606470, COSV62821318; called by muse, mutect2, varscan2
- ZNF91 | c.354G>C p.E118D | Missense Mutation (SNP) | VAF 28/71 reads (39%) | SIFT tolerated (0.21); PolyPhen benign (0.028); catalogued as COSV56083019; called by muse, mutect2, varscan2
- ABCA7 | c.638C>G p.T213S | Missense Mutation (SNP) | VAF 16/204 reads (8%) | SIFT tolerated (0.92); PolyPhen benign (0); called by muse, mutect2
- ACSM4 | c.1580A>G p.Y527C | Missense Mutation (SNP) | VAF 60/171 reads (35%) | SIFT tolerated (0.08); PolyPhen benign (0); called by muse, mutect2, varscan2
- ADGRB3 | c.469G>C p.V157L | Missense Mutation (SNP) | VAF 22/163 reads (13%) | SIFT tolerated (0.5); PolyPhen possibly damaging (0.846); called by muse, mutect2, varscan2
- ADGRF5 | c.2345C>T p.T782I | Missense Mutation (SNP) | VAF 30/80 reads (38%) | SIFT deleterious (0); PolyPhen possibly damaging (0.871); called by muse, mutect2, varscan2
- ADGRV1 | c.635C>A p.A212E | Missense Mutation (SNP) | VAF 14/153 reads (9%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.978); called by muse, mutect2
- AHNAK | c.13545A>C p.K4515N | Missense Mutation (SNP) | VAF 40/389 reads (10%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.995); called by muse, mutect2
- APOB | c.9626A>G p.E3209G | Missense Mutation (SNP) | VAF 21/91 reads (23%) | SIFT deleterious (0); PolyPhen benign (0.253); called by muse, mutect2, varscan2
- ARFGEF3 | c.694del p.L232Wfs*24 | Frame Shift Del (DEL) | VAF 28/277 reads (10%) | called by mutect2, pindel, varscan2
- ASIC2 | c.1413C>G p.D471E | Missense Mutation (SNP) | VAF 43/237 reads (18%) | SIFT tolerated (0.55); PolyPhen benign (0); called by muse, mutect2, varscan2
- ATAD2B | c.3196G>T p.E1066* | Nonsense Mutation (SNP) | VAF 14/187 reads (7%) | called by muse, mutect2
- ATP2A2 | c.1813G>T p.E605* | Nonsense Mutation (SNP) | VAF 30/356 reads (8%) | called by muse, mutect2
- BCL6B | c.104G>T p.G35V | Missense Mutation (SNP) | VAF 33/306 reads (11%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.939); called by muse, mutect2, varscan2
- BCL7C | c.217dup p.E73Gfs*21 | Frame Shift Ins (INS) | VAF 25/142 reads (18%) | called by mutect2, pindel, varscan2
- C2orf73 | c.772G>T p.E258* | Nonsense Mutation (SNP) | VAF 19/155 reads (12%) | called by muse, mutect2, varscan2
- CA12 | c.1042A>G p.M348V | Missense Mutation (SNP) | VAF 64/461 reads (14%) | SIFT tolerated (0.14); PolyPhen benign (0); called by muse, mutect2, varscan2
- CCDC57 | c.703A>T p.N235Y | Missense Mutation (SNP) | VAF 35/280 reads (13%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.886); called by muse, mutect2, varscan2
- CNTNAP1 | c.241C>T p.R81W | Missense Mutation (SNP) | VAF 35/250 reads (14%) | SIFT deleterious (0); PolyPhen possibly damaging (0.85); called by muse, mutect2, varscan2
- EBF4 | c.913C>T p.R305W (on ENST00000609451; = p.R301W on NM_001110514.1) | Missense Mutation (SNP) | VAF 8/98 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); called by muse, mutect2
- EEA1 | c.1076C>G p.S359* | Nonsense Mutation (SNP) | VAF 54/396 reads (14%) | called by muse, mutect2, varscan2
- FAH | c.305_307dup p.L102dup | In Frame Ins (INS) | VAF 34/263 reads (13%) | called by mutect2, pindel
- FAM25C | c.17G>C p.G6A | Missense Mutation (SNP) | VAF 47/484 reads (10%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.959); called by muse, mutect2, varscan2
- FARSA | c.320C>T p.A107V | Missense Mutation (SNP) | VAF 20/195 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.977); called by muse, mutect2, varscan2
- FBN3 | c.6182G>T p.S2061I | Missense Mutation (SNP) | VAF 45/201 reads (22%) | SIFT tolerated (0.12); PolyPhen benign (0.22); called by muse, mutect2, varscan2
- FBXO46 | c.160G>C p.E54Q | Missense Mutation (SNP) | VAF 30/263 reads (11%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.74); called by muse, mutect2, varscan2
- FFAR1 | c.141C>A p.N47K | Missense Mutation (SNP) | VAF 111/472 reads (24%) | SIFT deleterious (0.03); PolyPhen benign (0.098); called by muse, mutect2, varscan2
- FGD3 | c.500A>T p.H167L | Missense Mutation (SNP) | VAF 100/307 reads (33%) | SIFT tolerated (0.28); PolyPhen benign (0.098); called by muse, mutect2, varscan2
- FOXC2 | c.1421A>C p.N474T | Missense Mutation (SNP) | VAF 103/1004 reads (10%) | SIFT deleterious (0.03); PolyPhen benign (0.037); called by muse, mutect2, varscan2
- FRG2 | c.473G>A p.R158Q | Missense Mutation (SNP) | VAF 69/773 reads (9%) | SIFT tolerated (0.21); PolyPhen benign (0.003); called by muse, mutect2
- GHDC | c.136T>A p.W46R | Missense Mutation (SNP) | VAF 82/706 reads (12%) | SIFT deleterious (0); PolyPhen benign (0.049); called by muse, varscan2
- GJA10 | c.595G>T p.D199Y | Missense Mutation (SNP) | VAF 32/243 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.967); called by muse, mutect2, varscan2
- IGKV1-5 | c.84G>C p.Q28H | Missense Mutation (SNP) | VAF 157/639 reads (25%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.705); called by muse, mutect2, varscan2
- IL7 | c.516G>A p.M172I | Missense Mutation (SNP) | VAF 27/179 reads (15%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.03); called by muse, mutect2, varscan2
- KIF13A | c.4934G>C p.R1645T | Missense Mutation (SNP) | VAF 30/260 reads (12%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0); called by muse, mutect2, varscan2
- KIFBP | c.1212T>A p.F404L | Missense Mutation (SNP) | VAF 139/483 reads (29%) | SIFT tolerated (0.85); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- KPNA3 | c.1300G>T p.G434C | Missense Mutation (SNP) | VAF 29/130 reads (22%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- KREMEN2 | c.740G>A p.W247* | Nonsense Mutation (SNP) | VAF 46/433 reads (11%) | called by muse, mutect2
- LYST | c.8111A>T p.E2704V | Missense Mutation (SNP) | VAF 6/91 reads (7%) | SIFT deleterious (0.02); PolyPhen benign (0.342); called by muse, mutect2
- MAZ | c.818A>T p.K273M | Missense Mutation (SNP) | VAF 44/405 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.959); called by muse, mutect2, varscan2
- MEGF8 | c.1822C>T p.L608F | Missense Mutation (SNP) | VAF 64/238 reads (27%) | SIFT tolerated (0.23); PolyPhen benign (0.038); called by muse, mutect2, varscan2
- MRPS24 | c.390C>A p.H130Q | Missense Mutation (SNP) | VAF 105/533 reads (20%) | SIFT tolerated (0.34); PolyPhen benign (0.019); called by muse, mutect2, varscan2
- MTARC1 | c.399C>G p.D133E | Missense Mutation (SNP) | VAF 26/292 reads (9%) | SIFT tolerated (0.69); PolyPhen benign (0.028); called by muse, mutect2
- MTMR2 | c.346dup p.S116Kfs*19 | Frame Shift Ins (INS) | VAF 65/248 reads (26%) | called by mutect2, pindel, varscan2
- MYCN | c.799G>C p.D267H | Missense Mutation (SNP) | VAF 21/163 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.954); called by muse, mutect2, varscan2
- NFKB1 | c.130C>G p.L44V (on ENST00000394820 / NM_001382627.1; = p.L45V on NM_003998.4 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 29/187 reads (16%) | SIFT deleterious (0); PolyPhen possibly damaging (0.725); called by muse, mutect2, varscan2
- NOM1 | c.2270C>A p.T757K | Missense Mutation (SNP) | VAF 32/124 reads (26%) | SIFT tolerated (0.38); PolyPhen benign (0.09); called by muse, mutect2, varscan2
- OGFR | c.1193A>T p.E398V | Missense Mutation (SNP) | VAF 68/748 reads (9%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.737); called by muse, mutect2
- PDZD8 | c.2830C>T p.R944C | Missense Mutation (SNP) | VAF 56/178 reads (31%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- PKP1 | c.92T>C p.M31T | Missense Mutation (SNP) | VAF 128/793 reads (16%) | SIFT deleterious (0.02); PolyPhen benign (0.062); called by muse, mutect2, varscan2
- PKP4 | c.2861A>C p.K954T | Missense Mutation (SNP) | VAF 29/110 reads (26%) | SIFT deleterious (0); PolyPhen possibly damaging (0.894); called by muse, mutect2, varscan2
- PPFIBP1 | c.982G>C p.D328H (on ENST00000318304 / NM_177444.3; = p.D308H on NM_003622.4) | Missense Mutation (SNP) | VAF 45/262 reads (17%) | SIFT deleterious (0); PolyPhen possibly damaging (0.62); called by muse, mutect2, varscan2
- RABEPK | c.990_991insTA p.K331* | Frame Shift Ins (INS) | VAF 61/223 reads (27%) | called by mutect2, pindel, varscan2
- REST | c.977A>C p.H326P | Missense Mutation (SNP) | VAF 15/53 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.972); called by muse, mutect2, varscan2
- RMND5A | c.381del p.R128Dfs*19 | Frame Shift Del (DEL) | VAF 37/244 reads (15%) | called by mutect2, pindel, varscan2
- RTL9 | c.1871C>T p.S624L | Missense Mutation (SNP) | VAF 28/99 reads (28%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.646); called by muse, mutect2, varscan2
- SCP2D1 | c.368T>G p.M123R | Missense Mutation (SNP) | VAF 74/419 reads (18%) | SIFT deleterious (0); PolyPhen benign (0.433); called by muse, mutect2, varscan2
- SLC12A6 | c.2993C>T p.S998F (on ENST00000354181 / NM_001365088.1; = p.S947F on NM_005135.2) | Missense Mutation (SNP) | VAF 64/463 reads (14%) | SIFT deleterious (0.03); PolyPhen benign (0.212); called by muse, mutect2, varscan2
- SLC1A3 | c.1353G>C p.M451I | Missense Mutation (SNP) | VAF 49/522 reads (9%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.777); called by muse, mutect2, varscan2
- SLIT1 | c.3547C>A p.Q1183K | Missense Mutation (SNP) | VAF 30/220 reads (14%) | SIFT tolerated (1); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- SORCS3 | c.2688G>T p.E896D | Missense Mutation (SNP) | VAF 80/249 reads (32%) | SIFT tolerated (0.09); PolyPhen benign (0.101); called by muse, mutect2, varscan2
- SPATA31A6 | c.555G>C p.Q185H | Missense Mutation (SNP) | VAF 6/20 reads (30%) | SIFT tolerated (0.19); PolyPhen possibly damaging (0.904); called by mutect2, varscan2
- TRIM28 | c.1222A>G p.I408V | Missense Mutation (SNP) | VAF 40/359 reads (11%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.847); called by muse, mutect2, varscan2
- TRIM60 | c.848A>T p.Y283F | Missense Mutation (SNP) | VAF 25/53 reads (47%) | SIFT tolerated (0.08); PolyPhen benign (0.325); called by muse, mutect2, varscan2
- UBR1 | c.1276A>G p.T426A | Missense Mutation (SNP) | VAF 25/77 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); called by muse, mutect2, varscan2
- VHL | c.419dup p.N141Qfs*3 | Frame Shift Ins (INS) | VAF 107/347 reads (31%) | called by mutect2, pindel, varscan2
- WASHC5 | c.2425C>T p.P809S | Missense Mutation (SNP) | VAF 45/738 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); called by muse, mutect2
- WDR76 | c.1610C>A p.T537N | Missense Mutation (SNP) | VAF 17/205 reads (8%) | SIFT deleterious (0.02); PolyPhen benign (0.041); called by muse, mutect2
- XRN1 | c.2001C>G p.H667Q | Missense Mutation (SNP) | VAF 20/160 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.945); called by muse, mutect2, varscan2
- ZDHHC13 | c.296del p.K99Sfs*10 | Frame Shift Del (DEL) | VAF 24/95 reads (25%) | called by mutect2, pindel, varscan2
- ZNF100 | c.1376G>T p.C459F | Missense Mutation (SNP) | VAF 101/471 reads (21%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- ZNF354B | c.1572T>G p.C524W | Missense Mutation (SNP) | VAF 116/223 reads (52%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- ZNF839 | c.679C>G p.P227A (on ENST00000558850 / NM_001267827.1; = p.P343A on NM_018335.5) | Missense Mutation (SNP) | VAF 125/236 reads (53%) | SIFT tolerated (0.07); PolyPhen benign (0.218); called by muse, mutect2, varscan2
- AGAP2 | c.1233G>T p.V411= (on ENST00000547588 / NM_001122772.2; = p.V75= on NM_014770.4) | Silent (SNP) | VAF 32/344 reads (9%) | called by muse, mutect2
- ASXL3 | c.387T>C p.S129= | Silent (SNP) | VAF 29/115 reads (25%) | called by muse, mutect2, varscan2
- CD36 | c.711C>G p.S237= | Silent (SNP) | VAF 45/225 reads (20%) | called by muse, mutect2, varscan2
- CYLD | c.1671C>T p.R557= | Silent (SNP) | VAF 45/369 reads (12%) | catalogued as COSV61094416; called by muse, mutect2, varscan2
- DCAF8L1 | c.1594C>A p.R532= | Silent (SNP) | VAF 9/44 reads (20%) | catalogued as COSV71595308; called by muse, mutect2, varscan2
- DCHS2 | c.1332G>A p.A444= | Silent (SNP) | VAF 16/126 reads (13%) | called by muse, mutect2, varscan2
- DLL3 | c.846G>A p.P282= | Silent (SNP) | VAF 168/617 reads (27%) | catalogued as rs372831253; called by muse, mutect2, varscan2
- GIMAP1 | c.339C>T p.H113= | Silent (SNP) | VAF 15/105 reads (14%) | catalogued as rs370175882, COSV56189436; called by muse, mutect2
- GNL1 | c.849G>A p.R283= | Silent (SNP) | VAF 33/155 reads (21%) | called by muse, mutect2, varscan2
- GP5 | c.951G>A p.R317= | Silent (SNP) | VAF 39/119 reads (33%) | called by muse, mutect2, varscan2
- GREM2 | c.354G>A p.Q118= | Silent (SNP) | VAF 38/271 reads (14%) | catalogued as COSV58952337; called by muse, mutect2, varscan2
- GRIP1 | c.909C>T p.S303= | Silent (SNP) | VAF 111/605 reads (18%) | catalogued as rs756398846, COSV54030059; called by muse, mutect2, varscan2
- LRP1 | c.3976C>T p.L1326= | Silent (SNP) | VAF 134/314 reads (43%) | called by muse, mutect2, varscan2
- LRRC41 | c.2365C>A p.R789= | Silent (SNP) | VAF 32/241 reads (13%) | catalogued as rs1435534462; called by muse, mutect2, varscan2
- MASP2 | c.927C>T p.G309= | Silent (SNP) | VAF 20/132 reads (15%) | called by muse, mutect2, varscan2
- MOGAT3 | c.678G>T p.L226= | Silent (SNP) | VAF 23/85 reads (27%) | catalogued as rs529546839; called by muse, mutect2, varscan2
- MRPL32 | c.438G>C p.G146= | Silent (SNP) | VAF 33/305 reads (11%) | called by muse, mutect2, varscan2
- OR11L1 | c.684C>T p.I228= | Silent (SNP) | VAF 77/650 reads (12%) | called by muse, mutect2, varscan2
- PLEC | c.10752C>G p.L3584= (on ENST00000322810 / NM_201380.4; = p.L3474= on NM_000445.5) | Silent (SNP) | VAF 20/364 reads (5%) | catalogued as rs1284354682; called by muse, mutect2
- PPP1R12B | c.2604C>T p.A868= | Silent (SNP) | VAF 9/128 reads (7%) | called by muse, mutect2
- PRDM7 | c.519G>A p.R173= | Silent (SNP) | VAF 63/297 reads (21%) | catalogued as rs1350372110; called by muse, mutect2, varscan2
- PTGER3 | c.709C>T p.L237= | Silent (SNP) | VAF 21/132 reads (16%) | called by muse, mutect2, varscan2
- RESF1 | c.726G>A p.L242= | Silent (SNP) | VAF 47/203 reads (23%) | called by muse, mutect2, varscan2
- RGS21 | c.81C>T p.A27= | Silent (SNP) | VAF 51/231 reads (22%) | called by muse, mutect2, varscan2
- RGSL1 | c.2205G>A p.T735= | Silent (SNP) | VAF 35/133 reads (26%) | called by muse, mutect2, varscan2
- SLC35B2 | c.165C>T p.L55= | Silent (SNP) | VAF 50/220 reads (23%) | called by muse, mutect2, varscan2
- STK11IP | c.1815A>G p.S605= | Silent (SNP) | VAF 43/343 reads (13%) | called by muse, mutect2, varscan2
- TMC7 | c.756T>A p.I252= | Silent (SNP) | VAF 21/200 reads (11%) | catalogued as rs1176785582; called by muse, mutect2
- TMEM9B | c.489C>G p.R163= | Silent (SNP) | VAF 28/273 reads (10%) | called by muse, mutect2, varscan2
- WDR90 | c.147C>T p.V49= | Silent (SNP) | VAF 43/349 reads (12%) | called by muse, mutect2, varscan2
- ZFHX4 | c.6570T>C p.D2190= | Silent (SNP) | VAF 33/198 reads (17%) | called by muse, mutect2, varscan2
- ZIC1 | c.306C>T p.F102= | Silent (SNP) | VAF 30/261 reads (11%) | called by muse, mutect2, varscan2
- ZSWIM2 | c.1293A>G p.L431= | Silent (SNP) | VAF 6/45 reads (13%) | catalogued as COSV54576580; called by muse, mutect2
- BCAT1 | c.7-1067C>T | Intron (SNP) | VAF 178/420 reads (42%) | called by muse, mutect2, varscan2
- CCNYL2 | n.624-2589C>A | Intron (SNP) | VAF 65/423 reads (15%) | catalogued as rs1401325742; called by muse, mutect2, varscan2
- DNM1L | c.-7C>T | 5'UTR (SNP) | VAF 25/311 reads (8%) | catalogued as rs754614254; called by muse, mutect2
- EMBP1 | n.938A>G | RNA (SNP) | VAF 27/275 reads (10%) | called by muse, mutect2, varscan2
- FMNL3 | c.-14G>A | 5'UTR (SNP) | VAF 16/64 reads (25%) | catalogued as rs1464099861; called by muse, mutect2, varscan2
- GPI | c.122+428G>C | Intron (SNP) | VAF 13/124 reads (10%) | catalogued as rs756216935; called by muse, mutect2, varscan2
- HMGXB4 | c.-7G>T | 5'UTR (SNP) | VAF 34/241 reads (14%) | called by muse, mutect2, varscan2
- HSPA8 | c.565-36del | Intron (DEL) | VAF 47/163 reads (29%) | called by mutect2, pindel, varscan2
- LMBR1L | c.1082+73T>C | Intron (SNP) | VAF 34/114 reads (30%) | called by muse, varscan2
- NSD2 | c.2138-62A>G | Intron (SNP) | VAF 32/310 reads (10%) | called by muse, mutect2
- OR1F2P | n.355_361del | RNA (DEL) | VAF 74/386 reads (19%) | called by mutect2, pindel, varscan2
- PLCE1 | c.1207-43014C>T | Intron (SNP) | VAF 36/244 reads (15%) | catalogued as rs770158413; called by muse, mutect2, varscan2
- RAB11B | c.40+14G>T | Intron (SNP) | VAF 7/125 reads (6%) | called by muse, mutect2
- RARRES2 | c.*102A>T | 3'UTR (SNP) | VAF 49/280 reads (18%) | called by muse, mutect2, varscan2
- RMND5B | c.*1635G>T | 3'UTR (SNP) | VAF 21/182 reads (12%) | called by muse, mutect2, varscan2
- TLE5 | c.189+14G>A | Intron (SNP) | VAF 71/213 reads (33%) | catalogued as rs757140015; called by muse, mutect2, varscan2
- XIRP2 | c.*962A>T | 3'UTR (SNP) | VAF 16/114 reads (14%) | called by muse, mutect2, varscan2
- YIPF3 | c.395+356C>T | Intron (SNP) | VAF 16/168 reads (10%) | catalogued as rs1357541887; called by muse, mutect2
